Somatic mutation profile of tumor specimen 0DQVIC from CCDI case PBCCXV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Liver; Age at diagnosis: 0.7 years (246 days).
Specimen 0DQVIC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e686c14-2aab-4218-bc49-f0685025b008.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQVIV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/326a0a88-0454-4001-8711-7e3f6d01c246

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLSCR3 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 328/1702 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs774115089; called by muse, mutect2, varscan2
- SPTBN1 | c.4958A>G p.K1653R | Missense Mutation (SNP) | VAF 569/1898 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs756344811; called by muse, mutect2, varscan2
